Somatic mutation profile of tumor specimen TARGET-30-PARVLK-01A (aliquot TARGET-30-PARVLK-01A-01D) from TARGET case TARGET-30-PARVLK, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 16.5 years (6,021 days).
Specimen TARGET-30-PARVLK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03a00938-0333-40ef-9eba-267121fecc5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARVLK-14A (Bone Marrow Normal), aliquot TARGET-30-PARVLK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8aba39c2-adeb-4436-be22-8741a9a46185

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.2031C>G p.H677Q (on ENST00000326724 / NM_001080395.3; = p.H574Q on NM_004920.2) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1568220726, COSV58373075; called by muse, mutect2
- ALDH6A1 | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV63247129; called by muse, mutect2
- ANKS6 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62052120; called by muse, mutect2
- CARD6 | c.2779C>A p.P927T | Missense Mutation (SNP) | VAF 112/179 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV54568965; called by muse, mutect2, varscan2
- CDCA7L | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV62258472; called by muse, mutect2, varscan2
- CEP350 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62486217; called by muse, mutect2, varscan2
- CHEK2 | c.605A>G p.Y202C (on ENST00000382580 / NM_001005735.2; = p.Y159C on NM_007194.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1060502718, COSV60425978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLHC1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV63427313; called by muse, mutect2, varscan2
- COL4A1 | c.1427G>C p.R476P | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV65431793; called by muse, mutect2, varscan2
- CPA1 | c.932T>A p.L311H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50575191; called by muse, mutect2, varscan2
- CTSZ | c.797C>A p.P266Q | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.768); catalogued as COSV53884773; called by muse, mutect2, varscan2
- HECTD1 | c.6618C>T p.H2206= | Splice Region (SNP) | VAF 6/31 reads (19%) | catalogued as rs760454073, COSV67949034; called by muse, mutect2, varscan2
- HIVEP2 | c.4024G>A p.V1342I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs760320989, COSV50017693; called by muse, mutect2, varscan2
- IFI44 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66075665; called by muse, mutect2, varscan2
- NLRP2 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs267605682, COSV54753356; called by muse, mutect2, varscan2
- OR7A17 | c.777C>G p.Y259* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV59415158; called by muse, mutect2, varscan2
- OTOGL | c.5640G>T p.W1880C (on ENST00000547103; = p.W1871C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54017874; called by muse, varscan2
- PRR16 | c.329C>G p.P110R (on ENST00000407149 / NM_001300783.2; = p.P87R on NM_016644.2) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV65405660; called by muse, mutect2, varscan2
- REEP3 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV53427218; called by muse, mutect2
- ROBO1 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1330717347, COSV71398377; called by muse, mutect2, varscan2
- TBC1D25 | c.509T>A p.L170H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV65124614; called by muse, mutect2, varscan2
- WDR37 | c.1321C>G p.R441G | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54131553; called by muse, mutect2, varscan2
- WNK3 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63615830; called by muse, mutect2, varscan2
- AHNAK | c.16272C>A p.A5424= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV57229502; called by muse, mutect2, varscan2
- CES2 | c.1326C>A p.P442= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV57697791; called by muse, mutect2, varscan2
- COL9A2 | c.1908G>A p.K636= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1458098171; called by muse, mutect2
- CTTNBP2 | c.3969C>A p.A1323= | Silent (SNP) | VAF 59/178 reads (33%) | catalogued as rs747322754, COSV50471888; called by muse, mutect2, varscan2
- SPATA31D1 | c.4239A>C p.L1413= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV61201062; called by muse, mutect2, varscan2
- ZNF501 | c.168A>C p.G56= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV101247160, COSV68516279, COSV68516668; called by muse, mutect2
- KIR3DX1 | n.697G>T | RNA (SNP) | VAF 23/47 reads (49%) | catalogued as COSV99683188; called by muse, mutect2, varscan2
